Somatic mutation profile of tumor specimen TCGA-OR-A5J3-01A (aliquot TCGA-OR-A5J3-01A-11D-A29I-10) from TCGA case TCGA-OR-A5J3, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 23.6 years (8,624 days).
Specimen TCGA-OR-A5J3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 338e9bc2-74cb-4f0b-afb9-3f447a21e7c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5J3-10A (Blood Derived Normal), aliquot TCGA-OR-A5J3-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d77b8c4e-6de6-4760-a2a3-fd9b7a1c9b11

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRM | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 106/119 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs74947284, COSV65755427; called by muse, mutect2, varscan2
- CNTN5 | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 110/120 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54316060; called by muse, mutect2, varscan2
- DNAH5 | c.3717C>A p.F1239L | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV54226634; called by muse, mutect2, varscan2
- GPR174 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 82/99 reads (83%) | catalogued as rs1333054510, COSV52133979; called by muse, mutect2, varscan2
- ARID3A | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1 | c.1828T>A p.Y610N | Missense Mutation (SNP) | VAF 82/95 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPFIA2 | c.940A>G p.K314E | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TLR9 | c.2708C>A p.A903E | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.754); called by muse, mutect2
- ADGRF3 | c.1017T>C p.L339= (on ENST00000311519 / NM_001145168.1; = p.L140= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 245/280 reads (88%) | called by muse, varscan2
- DVL1 | c.1623G>A p.Q541= (on ENST00000378888 / NM_001330311.2; = p.Q516= on NM_004421.3) | Silent (SNP) | VAF 24/27 reads (89%) | catalogued as COSV59562790; called by muse, mutect2, varscan2
- PCDHA12 | c.42G>C p.L14= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV56503119; called by muse, mutect2, varscan2
- PPWD1 | c.1461T>A p.P487= | Silent (SNP) | VAF 85/164 reads (52%) | called by muse, mutect2, varscan2
- IFNAR2 | c.841-102G>A | Intron (SNP) | VAF 11/25 reads (44%) | catalogued as rs777044815; called by muse, mutect2, varscan2
